Somatic mutation profile of cancer-model specimen HCM-BROD-0597-C64-85A (2D Modified Conditionally Reprogrammed Cells, passage 10; aliquot HCM-BROD-0597-C64-85A-01D-A85C-36), derived from the primary tumor of HCMI case HCM-BROD-0597-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 1.5 years (533 days).
Specimen HCM-BROD-0597-C64-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a554891-2af5-4843-933b-e08dc086518f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0597-C64-10A (Blood Derived Normal), aliquot HCM-BROD-0597-C64-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09c7dd8f-4a04-49db-8454-7bac1f8797d5

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 228/470 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL22A1 | c.2014G>A p.G672S | Missense Mutation (SNP) | VAF 162/474 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs756630962, COSV57324838; called by muse, mutect2, varscan2
- EPHA7 | c.1385C>A p.S462Y | Missense Mutation (SNP) | VAF 134/306 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV65177989; called by muse, varscan2
- RP1L1 | c.5968G>A p.E1990K | Missense Mutation (SNP) | VAF 24/660 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.546); catalogued as rs1410329134, COSV66758181; called by muse, mutect2
- WT1 | c.1072_1073del p.R358Cfs*14 | Frame Shift Del (DEL) | VAF 230/376 reads (61%) | catalogued as rs1271668369; called by pindel, varscan2
- YTHDC2 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.893); catalogued as COSV50747291, COSV50752350; called by muse, mutect2
- COL22A1 | c.4004C>A p.P1335Q | Missense Mutation (SNP) | VAF 160/406 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- DPP6 | c.1507C>A p.L503M (on ENST00000377770 / NM_001364500.2; = p.L441M on NM_001936.5) | Missense Mutation (SNP) | VAF 20/518 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- IL13 | c.82del p.G29Afs*44 | Frame Shift Del (DEL) | VAF 219/649 reads (34%) | called by mutect2, pindel, varscan2
- NOD1 | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 22/492 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by muse, mutect2
- TRIM40 | c.19G>C p.D7H | Missense Mutation (SNP) | VAF 145/469 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- LCP1 | c.75C>A p.G25= | Silent (SNP) | VAF 13/295 reads (4%) | called by muse, mutect2
- PLAG1 | c.66A>G p.K22= | Silent (SNP) | VAF 17/290 reads (6%) | called by muse, mutect2
- TAOK2 | c.3276G>T p.L1092= | Silent (SNP) | VAF 25/747 reads (3%) | called by muse, mutect2
